Somatic mutation profile of tumor specimen 0DUME2 from CCDI case PBCKVW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Nodular melanoma; Tissue or organ of origin: Skin of upper limb and shoulder; Age at diagnosis: 14.3 years (5,220 days).
Specimen 0DUME2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 28ec05e3-256e-4e4c-9c21-795330bbf2e0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUMDL (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7183237b-433a-4d13-8fa5-c906f1b0f5a5

The open-access MAF lists 202 somatic variants for this specimen: 121 protein-altering or splice-affecting, 51 silent, 30 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 107, Silent 51, Intron 15, Nonsense Mutation 9, 3'UTR 5, 5'UTR 4, 5'Flank 3, 3'Flank 3, Splice Site 3, Splice Region 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 306/785 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, varscan2
- MAST1 | c.1549G>A p.G517S | Missense Mutation (SNP) | VAF 78/377 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1568413207, COSV99262152; ClinVar: pathogenic; called by muse, varscan2
- A2ML1 | c.3710C>T p.S1237F | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1181948169, COSV55289803, COSV55299040; called by muse, varscan2
- ABCA13 | c.14281A>G p.S4761G | Missense Mutation (SNP) | VAF 83/485 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as rs1349489025; called by muse, varscan2
- ABCG1 | c.1988G>A p.R663H | Missense Mutation (SNP) | VAF 90/511 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs919514504, COSV59201752; called by muse, varscan2
- ADAM21 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV50793793; called by muse, varscan2
- ADAMTS18 | c.3281G>A p.R1094Q | Missense Mutation (SNP) | VAF 44/202 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as rs373807615, COSV51407429; called by muse, varscan2
- ADH1B | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 58/514 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as COSV59295195; called by muse, varscan2
- AGBL4 | c.40G>A p.D14N | Missense Mutation (SNP) | VAF 56/250 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1165228490; called by muse, varscan2
- AHDC1 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 68/320 reads (21%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.063); catalogued as rs762766581; called by muse, varscan2
- ASPG | c.1075G>A p.E359K | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as COSV71933640, COSV71933789; called by muse, varscan2
- BIRC3 | c.73G>A p.D25N | Missense Mutation (SNP) | VAF 57/563 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs370738985; called by muse, varscan2
- BRCA2 | c.4765C>T p.P1589S | Missense Mutation (SNP) | VAF 80/466 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.172); catalogued as COSV66449134; called by muse, varscan2
- C8orf37 | c.601C>T p.R201C | Missense Mutation (SNP) | VAF 161/591 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs750509315, COSV54414046; called by muse, varscan2
- CCDC27 | c.1312C>T p.L438F | Missense Mutation (SNP) | VAF 32/184 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs776720608; called by muse, varscan2
- CEACAM20 | c.401G>A p.G134E | Missense Mutation (SNP) | VAF 50/317 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57601235; called by muse, varscan2
- COL12A1 | c.3943G>A p.D1315N | Missense Mutation (SNP) | VAF 108/486 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); catalogued as rs185615367; called by muse, varscan2
- DPEP2 | c.307G>A p.G103R | Missense Mutation (SNP) | VAF 77/417 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV52055937; called by muse, varscan2
- EFCAB13 | c.2102T>C p.V701A | Missense Mutation (SNP) | VAF 78/550 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.006); catalogued as rs979269712; called by muse, varscan2
- EYS | c.6200G>A p.G2067E | Missense Mutation (SNP) | VAF 42/220 reads (19%) | SIFT tolerated (0.28); PolyPhen benign (0.01); catalogued as COSV101008343; called by muse, varscan2
- FAM117A | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 45/230 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.996); catalogued as rs1027541019; called by muse, varscan2
- GRIK3 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 51/230 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.668); catalogued as rs904254054, COSV66138084; called by muse, varscan2
- GRPR | c.841C>T p.H281Y | Missense Mutation (SNP) | VAF 64/157 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV66669319, COSV66670311; called by muse, varscan2
- HECTD4 | c.3748C>T p.P1250S | Missense Mutation (SNP) | VAF 56/265 reads (21%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.999); catalogued as rs775537781; called by muse, varscan2
- KBTBD3 | c.1727G>A p.R576K | Missense Mutation (SNP) | VAF 57/284 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.072); catalogued as rs993797448; called by muse, varscan2
- KCNC4 | c.1007C>T p.S336F | Missense Mutation (SNP) | VAF 56/170 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as rs1417916529, COSV63925219, COSV63926097; called by muse, varscan2
- KDM4C | c.1442C>T p.S481F | Missense Mutation (SNP) | VAF 54/328 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV67186339; called by muse, varscan2
- KIF2B | c.1646C>T p.P549L | Missense Mutation (SNP) | VAF 45/356 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1202681047, COSV52127349; called by muse, varscan2
- KLHL13 | c.484G>A p.D162N | Missense Mutation (SNP) | VAF 112/252 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.456); catalogued as rs764684320; called by muse, varscan2
- LIFR | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 108/662 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1360273931, COSV54690495; called by muse, varscan2
- LY86 | c.71G>A p.G24E | Missense Mutation (SNP) | VAF 110/629 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0.007); catalogued as rs267601098, COSV57912752; called by muse, varscan2
- MORC1 | c.2236G>A p.E746K | Missense Mutation (SNP) | VAF 44/326 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.355); catalogued as COSV51728868; called by muse, varscan2
- MORC1 | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.012); catalogued as COSV51718997, COSV51732652; called by muse, varscan2
- NASP | c.2179C>T p.P727S | Missense Mutation (SNP) | VAF 96/637 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.918); catalogued as rs1249734068; called by muse, varscan2
- OR10K2 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 60/234 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs773209382; called by muse, varscan2
- OR4A15 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 78/379 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.26); catalogued as rs1423687925, COSV59033796, COSV59035039; called by muse, varscan2
- OR5H14 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 66/439 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101454188, COSV71193926; called by muse, varscan2
- OSBPL8 | c.860C>T p.S287L | Missense Mutation (SNP) | VAF 92/442 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1183844682, COSV53887283; called by muse, varscan2
- PAK5 | c.1819C>T p.P607S | Missense Mutation (SNP) | VAF 88/439 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62035462; called by muse, varscan2
- PAK6 | c.1570C>T p.H524Y | Missense Mutation (SNP) | VAF 30/218 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1423018143; called by muse, varscan2
- PCDH15 | c.1007G>A p.R336Q | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs370442031, COSV57263745; called by muse, varscan2
- PCDHA11 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 42/245 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV56480358, COSV56484098; called by muse, varscan2
- PCDHA8 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 55/142 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs147078401; called by muse, varscan2
- PCDHB9 | c.2000C>T p.S667F | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.982); catalogued as rs1554283313; called by muse, varscan2
- PCDHGA1 | c.757G>A p.E253K | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs140226913, COSV65296451; called by muse, varscan2
- PDE3A | c.1094C>T p.S365F | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs199757276, COSV62983237; called by muse, varscan2
- PHLDB1 | c.1702C>T p.R568W | Missense Mutation (SNP) | VAF 30/190 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs573840606, COSV61879420; called by muse, varscan2
- RALGAPA2 | c.296G>A p.R99Q | Missense Mutation (SNP) | VAF 45/434 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as rs1287668959; called by muse, varscan2
- RASGRF2 | c.862G>A p.D288N | Missense Mutation (SNP) | VAF 62/365 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs889399240, COSV54122306; called by muse, varscan2
- RFWD3 | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 50/224 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.06); catalogued as rs1164100229, COSV63099388; called by muse, varscan2
- RORB | c.349G>A p.E117K (on ENST00000396204 / NM_001365023.1; = p.E106K on NM_006914.4) | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.313); catalogued as COSV65339619; called by muse, varscan2
- SCNN1G | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 52/326 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1159361673; called by muse, varscan2
- SGMS1 | c.189G>A p.M63I | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV62371122; called by muse, varscan2
- SLC17A9 | c.266G>A p.G89D | Missense Mutation (SNP) | VAF 41/253 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs74709668; called by muse, varscan2
- SYCP2L | c.1313-1G>A p.X438_splice | Splice Site (SNP) | VAF 72/362 reads (20%) | catalogued as COSV99305536; called by muse, varscan2
- TBXT | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs200268852, COSV51616859; called by muse, varscan2
- THSD7A | c.3172C>T p.R1058C | Missense Mutation (SNP) | VAF 70/376 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70263651; called by muse, varscan2
- TMEM151A | c.842G>A p.W281* | Nonsense Mutation (SNP) | VAF 101/558 reads (18%) | catalogued as rs1210203194; called by muse, varscan2
- TNXB | c.9280C>T p.L3094F (on ENST00000647633; = p.L2847F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/454 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs1470803069, COSV100926552; called by muse, varscan2
- TRPC7 | c.490G>A p.D164N | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs761777158, COSV100726085; called by muse, varscan2
- UGT3A2 | c.562C>T p.R188C | Missense Mutation (SNP) | VAF 44/223 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs761649425, COSV56928341; called by muse, varscan2
- ZNF469 | c.2015C>T p.P672L | Missense Mutation (SNP) | VAF 64/468 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV71258311; called by muse, varscan2
- ZNF511 | c.329C>T p.S110F | Missense Mutation (SNP) | VAF 121/444 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV62920239; called by muse, varscan2
- ZNF98 | c.352G>A p.E118K | Missense Mutation (SNP) | VAF 70/626 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.013); catalogued as COSV63334101; called by muse, varscan2
- ABLIM3 | c.1633C>T p.P545S | Missense Mutation (SNP) | VAF 68/286 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.031); called by muse, varscan2
- ADAMTS20 | c.4094G>A p.G1365E | Missense Mutation (SNP) | VAF 66/251 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); called by muse, varscan2
- ANKIB1 | c.598C>T p.Q200* | Nonsense Mutation (SNP) | VAF 124/854 reads (15%) | called by muse, varscan2
- APP | c.2270A>T p.Y757F | Missense Mutation (SNP) | VAF 120/590 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ARHGEF28 | c.4501C>T p.Q1501* | Nonsense Mutation (SNP) | VAF 34/116 reads (29%) | called by muse, varscan2
- ATAD3A | c.1583A>G p.E528G | Missense Mutation (SNP) | VAF 80/497 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, varscan2
- ATF6 | c.766C>T p.L256F | Missense Mutation (SNP) | VAF 66/340 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.094); called by muse, varscan2
- C2orf42 | c.394C>T p.Q132* | Nonsense Mutation (SNP) | VAF 84/450 reads (19%) | called by muse, varscan2
- C4BPA | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 66/437 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.961); called by muse, varscan2
- C4orf47 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 137/585 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, varscan2
- CCDC144A | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 48/352 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.052); called by muse, varscan2
- CCDC168 | c.15712C>T p.Q5238* | Nonsense Mutation (SNP) | VAF 49/233 reads (21%) | called by muse, varscan2
- CD86 | c.803G>A p.W268* (on ENST00000330540 / NM_175862.5; = p.W262* on NM_006889.4) | Nonsense Mutation (SNP) | VAF 64/434 reads (15%) | called by muse, varscan2
- CFAP47 | c.8236C>A p.P2746T | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.102); called by muse, varscan2
- COBL | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 100/499 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- COL5A1 | c.3254C>T p.P1085L | Missense Mutation (SNP) | VAF 64/340 reads (19%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, varscan2
- CPS1 | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 86/456 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0.023); called by muse, varscan2
- DEFB124 | c.59G>A p.G20E | Missense Mutation (SNP) | VAF 58/380 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- DLG5 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); called by muse, varscan2
- DSCAML1 | c.3509C>T p.S1170F (on ENST00000321322; = p.S1110F on NM_020693.4) | Missense Mutation (SNP) | VAF 47/294 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- DTX4 | c.940C>T p.P314S | Missense Mutation (SNP) | VAF 62/324 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, varscan2
- EMCN | c.238T>A p.F80I | Missense Mutation (SNP) | VAF 54/374 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, varscan2
- EXOC1L | c.506C>T p.P169L | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.149); called by muse, varscan2
- FCGBP | c.2444G>A p.W815* | Nonsense Mutation (SNP) | VAF 78/423 reads (18%) | called by muse, varscan2
- FMNL2 | c.1963G>A p.D655N | Missense Mutation (SNP) | VAF 56/236 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); called by muse, varscan2
- GANAB | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 60/555 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, varscan2
- KCNH7 | c.136G>A p.D46N | Missense Mutation (SNP) | VAF 65/401 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- KLHL31 | c.8C>T p.P3L | Missense Mutation (SNP) | VAF 94/500 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- MMRN1 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 100/444 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.028); called by muse, varscan2
- MROH2A | c.3700C>T p.Q1234* | Nonsense Mutation (SNP) | VAF 31/204 reads (15%) | called by muse, varscan2
- MUC2 | c.3508G>A p.D1170N | Missense Mutation (SNP) | VAF 36/314 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.001); called by muse, varscan2
- MYH11 | c.3499G>A p.E1167K | Missense Mutation (SNP) | VAF 36/224 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, varscan2
- MYH13 | c.5527G>A p.G1843R | Missense Mutation (SNP) | VAF 58/318 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); called by muse, varscan2
- MYH15 | c.150G>A p.G50= | Splice Region (SNP) | VAF 79/525 reads (15%) | called by muse, varscan2
- NOTUM | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 95/440 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.97); called by muse, varscan2
- OR52E1 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 90/402 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.949); called by muse, varscan2
- OR5L2 | c.800G>A p.S267N | Missense Mutation (SNP) | VAF 24/195 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.011); called by muse, varscan2
- PDCD1 | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 39/171 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.169); called by muse, varscan2
- PDE6C | c.1483-1G>A p.X495_splice | Splice Site (SNP) | VAF 72/196 reads (37%) | called by muse, varscan2
- PPP4R4 | c.189C>T p.L63= | Splice Region (SNP) | VAF 76/369 reads (21%) | called by muse, varscan2
- PRPF18 | c.788T>G p.V263G | Missense Mutation (SNP) | VAF 75/310 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, varscan2
- PTPRQ | c.3931C>T p.P1311S (on ENST00000616559; = p.P1269S on NM_001145026.2) | Missense Mutation (SNP) | VAF 50/404 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); called by muse, varscan2
- RAB6B | c.464C>T p.T155I | Missense Mutation (SNP) | VAF 94/496 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- RCAN2 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, varscan2
- RGL3 | c.2015-1G>A p.X672_splice | Splice Site (SNP) | VAF 28/157 reads (18%) | called by muse, varscan2
- SBK1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 44/356 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.516); called by muse, varscan2
- SEMA4D | c.1706G>A p.G569D | Missense Mutation (SNP) | VAF 124/611 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, varscan2
- SLC26A11 | c.676C>T p.H226Y | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.009); called by muse, varscan2
- SPACA6 | c.313C>T p.P105S | Missense Mutation (SNP) | VAF 106/538 reads (20%) | SIFT tolerated (0.33); PolyPhen benign (0.09); called by muse, varscan2
- ST8SIA5 | c.422A>T p.H141L | Missense Mutation (SNP) | VAF 94/456 reads (21%) | PolyPhen benign (0.186); called by muse, varscan2
- STARD13 | c.2447C>T p.P816L (on ENST00000336934 / NM_001243476.3; = p.P698L on NM_052851.3) | Missense Mutation (SNP) | VAF 93/422 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- SYK | c.512G>A p.G171E | Missense Mutation (SNP) | VAF 97/517 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, varscan2
- TICRR | c.5011C>T p.P1671S | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRIM49 | c.965C>T p.T322I | Missense Mutation (SNP) | VAF 39/334 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.459); called by muse, varscan2
- TRIM49 | c.964A>C p.T322P | Missense Mutation (SNP) | VAF 40/332 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.003); called by muse, varscan2
- WDFY4 | c.4312C>T p.Q1438* | Nonsense Mutation (SNP) | VAF 78/386 reads (20%) | called by muse, varscan2
- ZNF454 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 56/385 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, varscan2
- ADPRHL1 | c.579G>T p.G193= | Silent (SNP) | VAF 62/278 reads (22%) | called by muse, varscan2
- ANKRD31 | c.4356C>T p.I1452= | Silent (SNP) | VAF 52/380 reads (14%) | called by muse, varscan2
- ARMC12 | c.591C>T p.I197= (on ENST00000373866 / NM_001286574.2; = p.I224= on NM_145028.5) | Silent (SNP) | VAF 84/416 reads (20%) | catalogued as COSV55359901; called by muse, varscan2
- AVIL | c.951G>A p.K317= | Silent (SNP) | VAF 58/444 reads (13%) | called by muse, varscan2
- BTNL8 | c.537C>T p.S179= | Silent (SNP) | VAF 36/222 reads (16%) | catalogued as COSV99180521; called by muse, varscan2
- BX276092.9 | c.1359G>A p.L453= | Silent (SNP) | VAF 98/279 reads (35%) | called by muse, varscan2
- C2orf78 | c.1950C>T p.F650= | Silent (SNP) | VAF 43/370 reads (12%) | catalogued as COSV68516704, COSV68519366; called by muse, varscan2
- C3AR1 | c.726C>T p.L242= | Silent (SNP) | VAF 42/246 reads (17%) | catalogued as rs768955520; called by muse, varscan2
- CACNA1A | c.2226C>T p.A742= | Silent (SNP) | VAF 113/588 reads (19%) | called by muse, varscan2
- CDH23 | c.2874C>T p.I958= | Silent (SNP) | VAF 61/349 reads (17%) | catalogued as rs1210896928, COSV54926289; called by muse, varscan2
- CFAP45 | c.315C>T p.S105= | Silent (SNP) | VAF 52/379 reads (14%) | catalogued as COSV63650336, COSV63650568; called by muse, varscan2
- CFAP74 | c.549C>T p.F183= | Silent (SNP) | VAF 74/421 reads (18%) | catalogued as COSV54570824; called by muse, varscan2
- CPSF3 | c.1018T>C p.L340= | Silent (SNP) | VAF 60/422 reads (14%) | called by muse, varscan2
- DEUP1 | c.1686C>T p.F562= | Silent (SNP) | VAF 86/688 reads (13%) | catalogued as COSV53210250; called by muse, varscan2
- DNAAF1 | c.657T>C p.C219= | Silent (SNP) | VAF 147/728 reads (20%) | called by muse, varscan2
- DYTN | c.618C>T p.I206= | Silent (SNP) | VAF 82/401 reads (20%) | called by muse, varscan2
- ERBB2 | c.1158C>T p.A386= | Silent (SNP) | VAF 61/396 reads (15%) | catalogued as rs756999086; called by muse, varscan2
- GNRHR | c.132C>T p.F44= | Silent (SNP) | VAF 95/414 reads (23%) | called by muse, varscan2
- GRM3 | c.633C>A p.T211= | Silent (SNP) | VAF 31/222 reads (14%) | called by muse, varscan2
- HGD | c.99G>A p.Q33= | Silent (SNP) | VAF 85/401 reads (21%) | called by muse, varscan2
- ITPR1 | c.7024C>T p.L2342= (on ENST00000354582; = p.L2287= on NM_002222.7) | Silent (SNP) | VAF 104/545 reads (19%) | called by muse, varscan2
- KIF22 | c.1332C>T p.L444= | Silent (SNP) | VAF 62/388 reads (16%) | called by muse, varscan2
- MAGEE2 | c.1557C>T p.F519= | Silent (SNP) | VAF 101/276 reads (37%) | catalogued as COSV64898611; called by muse, varscan2
- MAST3 | c.822C>T p.I274= | Silent (SNP) | VAF 70/408 reads (17%) | called by muse, varscan2
- MICAL3 | c.897C>T p.F299= | Silent (SNP) | VAF 135/878 reads (15%) | catalogued as rs751823263, COSV52891604; called by muse, varscan2
- MRTFA | c.1791C>T p.L597= | Silent (SNP) | VAF 70/446 reads (16%) | catalogued as rs746901961, COSV62932206, COSV62935408; called by muse, varscan2
- MUC3A | c.5208C>T p.S1736= | Silent (SNP) | VAF 128/625 reads (20%) | catalogued as rs1277241729; called by muse, varscan2
- MYH13 | c.192C>T p.T64= | Silent (SNP) | VAF 22/204 reads (11%) | called by muse, varscan2
- OPHN1 | c.213C>T p.F71= | Silent (SNP) | VAF 122/306 reads (40%) | called by muse, varscan2
- OR10Z1 | c.339C>T p.F113= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as rs1176055881, COSV63524160; called by muse, varscan2
- OR4D2 | c.276C>T p.I92= | Silent (SNP) | VAF 68/298 reads (23%) | catalogued as COSV73459824; called by muse, varscan2
- OR51B2 | c.618C>T p.F206= | Silent (SNP) | VAF 40/198 reads (20%) | called by muse, varscan2
- OR5J2 | c.930C>T p.F310= | Silent (SNP) | VAF 82/378 reads (22%) | catalogued as COSV100399123; called by muse, varscan2
- PCDHGB5 | c.1698C>T p.D566= | Silent (SNP) | VAF 36/177 reads (20%) | catalogued as rs1439243162, COSV54025098; called by muse, varscan2
- PDE3A | c.1353C>T p.P451= | Silent (SNP) | VAF 67/290 reads (23%) | catalogued as rs769442819; called by muse, varscan2
- PFKL | c.1474C>T p.L492= | Silent (SNP) | VAF 63/410 reads (15%) | called by muse, varscan2
- PITPNM2 | c.1077C>T p.F359= | Silent (SNP) | VAF 94/516 reads (18%) | catalogued as rs1566239467; called by muse, varscan2
- PLXNA4 | c.2742C>T p.I914= | Silent (SNP) | VAF 142/281 reads (51%) | catalogued as rs748905519, COSV58118238, COSV58145890; called by muse, varscan2
- RIMS2 | c.4209G>A p.L1403= (on ENST00000666250 / NM_001348490.2; = p.L974= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 166/484 reads (34%) | called by muse, varscan2
- RNFT2 | c.1335G>A p.*445= | Silent (SNP) | VAF 76/511 reads (15%) | called by muse, varscan2
- SOX10 | c.534G>A p.R178= | Silent (SNP) | VAF 76/436 reads (17%) | catalogued as rs775852902; called by muse, varscan2
- SOX8 | c.1128C>T p.F376= | Silent (SNP) | VAF 47/245 reads (19%) | catalogued as rs755889006, COSV53508584; called by muse, varscan2
- SRCAP | c.6066C>T p.H2022= | Silent (SNP) | VAF 130/562 reads (23%) | called by muse, varscan2
- STRA6 | c.21G>A p.G7= | Silent (SNP) | VAF 110/496 reads (22%) | called by muse, varscan2
- TBX21 | c.1254C>T p.S418= | Silent (SNP) | VAF 32/170 reads (19%) | called by muse, varscan2
- TCTE1 | c.612C>T p.A204= | Silent (SNP) | VAF 86/432 reads (20%) | called by muse, varscan2
- TERB2 | c.81G>A p.T27= | Silent (SNP) | VAF 56/286 reads (20%) | catalogued as rs780955219, COSV100546590, COSV61650841; called by muse, varscan2
- XIRP2 | c.5212C>T p.L1738= (on ENST00000628543; = p.L1913= on NM_152381.6) | Silent (SNP) | VAF 117/628 reads (19%) | catalogued as COSV54743712, COSV99740190; called by muse, varscan2
- ZNF490 | c.1176T>C p.C392= | Silent (SNP) | VAF 91/474 reads (19%) | called by muse, varscan2
- ZNF574 | c.963C>T p.P321= | Silent (SNP) | VAF 52/354 reads (15%) | catalogued as rs778841816; called by muse, varscan2
- ZSCAN1 | c.609C>T p.S203= | Silent (SNP) | VAF 44/186 reads (24%) | catalogued as rs1205582026, COSV56605607, COSV56606144, COSV56607804; called by muse, varscan2
- ACOX2 | c.324-38C>T | Intron (SNP) | VAF 7/27 reads (26%) | called by muse, varscan2
- ANKRD11 | c.745-28C>T | Intron (SNP) | VAF 50/264 reads (19%) | called by muse, varscan2
- ARHGAP30 | c.665-10C>T | Intron (SNP) | VAF 60/332 reads (18%) | called by muse, varscan2
- BSDC1 | c.12-98C>T | Intron (SNP) | VAF 5/21 reads (24%) | catalogued as rs910975767; called by muse, varscan2
- CCDC180 | c.4842+27C>T | Intron (SNP) | VAF 42/208 reads (20%) | called by muse, varscan2
- CPLANE1 | c.*2911+57G>T | Intron (SNP) | VAF 16/104 reads (15%) | called by muse, varscan2
- CXCL12 | c.179+30G>A | Intron (SNP) | VAF 46/116 reads (40%) | catalogued as rs1481938049; called by muse, varscan2
- DCP1A | chr3:53347571 G>A | 5'Flank (SNP) | VAF 12/88 reads (14%) | catalogued as COSV99587812; called by muse, varscan2
- FAM47C | c.-4C>T | 5'UTR (SNP) | VAF 21/49 reads (43%) | called by muse, varscan2
- IGFN1 | c.1924+28G>A | Intron (SNP) | VAF 26/114 reads (23%) | catalogued as rs752486304; called by muse, varscan2
- MCAM | c.1550-15C>T | Intron (SNP) | VAF 22/126 reads (17%) | called by muse, varscan2
- MELTF | c.1939-19C>T | Intron (SNP) | VAF 32/146 reads (22%) | catalogued as COSV56382214; called by muse, varscan2
- MVB12A | c.413+91C>T | Intron (SNP) | VAF 8/17 reads (47%) | catalogued as rs989063795; called by muse, varscan2
- NPEPPS | c.2559+28T>C | Intron (SNP) | VAF 40/114 reads (35%) | called by muse, varscan2
- NRP2 | c.1904-28C>T | Intron (SNP) | VAF 45/247 reads (18%) | catalogued as rs758665537; called by muse, varscan2
- NUDT1 | chr7:2242229 G>A | 5'Flank (SNP) | VAF 32/245 reads (13%) | catalogued as rs1391802898; called by muse, varscan2
- OR2M3 | c.*64C>T | 3'UTR (SNP) | VAF 10/36 reads (28%) | called by muse, varscan2
- PKD1L2 | chr16:81167972 C>T | 3'Flank (SNP) | VAF 90/456 reads (20%) | called by muse, varscan2
- RARB | chr3:25596464 A>G | 3'Flank (SNP) | VAF 78/432 reads (18%) | called by muse, varscan2
- RNU1-143P | chr1:143796022 G>A | 5'Flank (SNP) | VAF 16/197 reads (8%) | called by muse, varscan2
- SKI | c.-16G>A | 5'UTR (SNP) | VAF 14/62 reads (23%) | called by muse, varscan2
- SKI | c.-15G>A | 5'UTR (SNP) | VAF 16/66 reads (24%) | called by muse, varscan2
- SLC7A1 | c.*15C>T | 3'UTR (SNP) | VAF 48/238 reads (20%) | catalogued as rs759409750; called by muse, varscan2
- SOHLH2 | c.-28C>T | 5'UTR (SNP) | VAF 30/154 reads (19%) | called by muse, varscan2
- SPANXB1 | c.*32G>A | 3'UTR (SNP) | VAF 24/120 reads (20%) | called by muse, varscan2
- TCHHL1 | chr1:152080606 G>A | 3'Flank (SNP) | VAF 68/576 reads (12%) | called by muse, varscan2
- TULP1 | c.1323+32C>T | Intron (SNP) | VAF 21/93 reads (23%) | called by muse, varscan2
- USH1C | c.*33G>A | 3'UTR (SNP) | VAF 45/379 reads (12%) | catalogued as COSV99142504; called by muse, varscan2
- VPS16 | c.*34C>T | 3'UTR (SNP) | VAF 26/176 reads (15%) | called by muse, varscan2
- ZDHHC3 | c.306+521C>T | Intron (SNP) | VAF 132/752 reads (18%) | called by muse, varscan2
